Somatic mutation profile of tumor specimen TCGA-B5-A0JX-01A (aliquot TCGA-B5-A0JX-01A-21D-A14K-09) from TCGA case TCGA-B5-A0JX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 62.5 years (22,834 days).
Specimen TCGA-B5-A0JX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1b59bd7-6135-4e5f-99d5-9e4421d6f864.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A0JX-10B (Blood Derived Normal), aliquot TCGA-B5-A0JX-10B-01D-A14K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a441999-9a81-4b31-b1fc-c47a8086bd0d

The open-access MAF lists 71 somatic variants for this specimen: 52 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 16, Frame Shift Del 4, Nonsense Mutation 4, Intron 2, Splice Region 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 62/192 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AKAP8 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762759792, COSV54102350; called by muse, mutect2, varscan2
- ALS2 | c.529G>A p.G177S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM125682, COSV51893701; called by muse, mutect2, varscan2
- ANO7 | c.226G>T p.A76S (on ENST00000274979; = p.A22S on NM_001001666.4) | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV99237222; called by muse, mutect2, varscan2
- ARHGAP35 | c.3779C>T p.P1260L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs1568473009, COSV101350677; called by muse, mutect2, varscan2
- ATXN7L3 | c.889G>A p.G297S (on ENST00000389384 / NM_001382309.1; = p.G304S on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.034); catalogued as rs1398214396, COSV100115971; called by muse, mutect2, varscan2
- C14orf39 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.147); catalogued as rs760565947, COSV100407199; called by muse, mutect2, varscan2
- CD248 | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs983956106, COSV100256457; called by muse, mutect2, varscan2
- CDRT1 | c.1339G>A p.V447I | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs759968722, COSV99887447; called by muse, varscan2
- CROT | c.42T>G p.F14L | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100519291; called by muse, mutect2, varscan2
- CTCF | c.1915C>T p.Q639* | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as COSV50547814; called by muse, mutect2, varscan2
- CXorf65 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1207399433, COSV99340035; called by muse, mutect2, varscan2
- EFCAB3 | c.371del p.P124Qfs*7 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as COSV59501153, COSV59503103; called by mutect2, pindel, varscan2
- FAT3 | c.12542G>A p.R4181H | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as rs368233172, COSV53170350; called by muse, mutect2, varscan2
- FRS2 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.04); catalogued as COSV100165687; called by muse, mutect2, varscan2
- FRS2 | c.692A>C p.E231A | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.01); catalogued as COSV100165689; called by muse, mutect2, varscan2
- HIPK4 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs766371069, COSV52526424; called by muse, mutect2, varscan2
- HPSE2 | c.1069C>G p.L357V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV100984803; called by muse, mutect2, varscan2
- IQSEC1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56229085; called by muse, mutect2, varscan2
- KAT5 | c.81C>A p.P27= | Splice Region (SNP) | VAF 43/113 reads (38%) | catalogued as COSV100383805; called by muse, mutect2, varscan2
- KCNC2 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV54368089; called by muse, mutect2, varscan2
- KIAA2026 | c.3498T>G p.N1166K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV101198824, COSV67355868; called by muse, mutect2, varscan2
- KRT82 | c.675G>T p.L225F | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99233356; called by muse, mutect2, varscan2
- MAGEC3 | c.296T>G p.L99R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); catalogued as COSV100024761; called by muse, mutect2, varscan2
- NUBP1 | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs1182069218, COSV99296604; called by muse, mutect2, varscan2
- PAPPA2 | c.4301G>A p.G1434E | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV100867496; called by muse, mutect2, varscan2
- PDXK | c.861G>T p.M287I | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99376009; called by muse, mutect2, varscan2
- PKDCC | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367778595, COSV99684626; called by muse, mutect2, varscan2
- PML | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs746515572, COSV51451672, COSV99166647; called by muse, mutect2, varscan2
- PODN | c.1523G>T p.R508L (on ENST00000395871; = p.R460L on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.229); catalogued as COSV100439304; called by muse, mutect2, varscan2
- PPFIA1 | c.1987C>T p.R663* | Nonsense Mutation (SNP) | VAF 26/83 reads (31%) | catalogued as COSV99556731; called by muse, mutect2, varscan2
- PPP1R12C | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 50/143 reads (35%) | catalogued as COSV99669947; called by muse, mutect2, varscan2
- PTEN | c.878del p.G293Efs*14 | Frame Shift Del (DEL) | VAF 9/15 reads (60%) | catalogued as COSV64306603; called by mutect2, pindel, varscan2
- REXO5 | c.1823G>C p.S608T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV99758912; called by muse, mutect2
- RPS3A | c.323A>T p.D108V | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99923599; called by muse, mutect2, varscan2
- SCN8A | c.4379T>C p.I1460T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100633159; called by muse, mutect2, varscan2
- SLC25A13 | c.1138A>T p.K380* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as COSV99672985; called by muse, mutect2, varscan2
- SLC25A13 | c.1137G>T p.K379N | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV99672995; called by muse, mutect2, varscan2
- SMC4 | c.1111G>C p.D371H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV100643902; called by muse, mutect2, varscan2
- SPACA3 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as rs375571299; called by muse, mutect2, varscan2
- SPATA31A1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 60/321 reads (19%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1416227731; called by muse, mutect2
- STX11 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.401); catalogued as COSV62450077; called by muse, mutect2, varscan2
- TAFA5 | c.302C>T p.P101L (on ENST00000402357 / NM_001082967.3; = p.P94L on NM_015381.7) | Missense Mutation (SNP) | VAF 77/112 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60971732; called by muse, mutect2, varscan2
- TERT | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57246912; called by muse, mutect2, varscan2
- TMEM225 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.071); catalogued as rs373538428; called by mutect2, varscan2
- XKR4 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); catalogued as rs1225097135, COSV100530605; called by muse, varscan2
- ZNF229 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs980634203, COSV52159278; called by muse, mutect2, varscan2
- ZNF536 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100835381, COSV62827327; called by muse, mutect2, varscan2
- ARID1A | c.6461_6476del p.F2154* | Frame Shift Del (DEL) | VAF 43/84 reads (51%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1143del p.I383Yfs*14 (on ENST00000521381 / NM_181523.3; = p.I113Yfs*14 on NM_181504.4) | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- PITPNB | c.769-2A>T p.X257_splice | Splice Site (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- SLC22A20P | n.1081G>C | Splice Region (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- ADAMTS1 | c.762G>A p.V254= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99535806; called by muse, mutect2
- DENND2B | c.876G>C p.L292= | Silent (SNP) | VAF 41/183 reads (22%) | catalogued as COSV100567092; called by muse, mutect2, varscan2
- DYSF | c.5748C>T p.F1916= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as COSV99244008; called by muse, mutect2, varscan2
- FSTL3 | c.228C>T p.H76= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV51261488; called by muse, mutect2, varscan2
- HYDIN | c.618G>T p.L206= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99861819, COSV99862074; called by mutect2, varscan2
- KRT19 | c.723G>A p.P241= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as rs140667731; called by muse, mutect2, varscan2
- MEF2D | c.1470C>T p.F490= | Silent (SNP) | VAF 44/134 reads (33%) | catalogued as rs747091040, COSV100559794; called by muse, mutect2, varscan2
- NAIP | c.21C>G p.A7= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99519099; called by muse, mutect2, varscan2
- OR7C1 | c.612C>T p.G204= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs760510816, COSV99934752; called by muse, mutect2, varscan2
- PRPF38B | c.45G>A p.Q15= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs948998806, COSV100898173; called by muse, mutect2, varscan2
- RFTN1 | c.1152C>G p.V384= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV100488732; called by muse, mutect2, varscan2
- RNF14 | c.936G>A p.P312= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs141694109, COSV61662332, COSV61663043; called by muse, mutect2, varscan2
- STAM2 | c.1389C>T p.N463= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs773766805, COSV99812828; called by muse, mutect2, varscan2
- TBC1D8B | c.69C>T p.N23= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV99343821; called by muse, mutect2, varscan2
- TRAPPC11 | c.762A>G p.V254= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100591638; called by mutect2, varscan2
- ZNF462 | c.1419C>T p.D473= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as rs148789863; called by muse, mutect2, varscan2
- DHRS4L1 | n.177-509G>C | Intron (SNP) | VAF 33/105 reads (31%) | called by muse, mutect2, varscan2
- LARS2 | c.*257G>A | 3'UTR (SNP) | VAF 14/46 reads (30%) | catalogued as rs374061060; called by muse, mutect2, varscan2
- PNPLA7 | c.31-209G>C | Intron (SNP) | VAF 56/136 reads (41%) | catalogued as rs1009279142, COSV99479968; called by muse, mutect2, varscan2
